Somatic mutation profile of tumor specimen TCGA-R6-A6Y0-01B (aliquot TCGA-R6-A6Y0-01B-11D-A33E-09) from TCGA case TCGA-R6-A6Y0, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 54.9 years (20,045 days).
Specimen TCGA-R6-A6Y0-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3deb4330-83a5-4d1e-b736-026e87864063.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6Y0-10A (Blood Derived Normal), aliquot TCGA-R6-A6Y0-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5793ba72-7936-4d30-9df2-e8c4b7f971ff

The open-access MAF lists 155 somatic variants for this specimen: 119 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 30, Nonsense Mutation 8, Frame Shift Del 3, RNA 3, Intron 2, Splice Site 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368687134; called by muse, mutect2, varscan2
- ADAM17 | c.644G>C p.R215T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV60397463; called by muse, mutect2, varscan2
- ATP8B3 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762490848, COSV59544974; called by muse, mutect2, varscan2
- CCDC63 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.138); catalogued as rs148044780; called by muse, mutect2, varscan2
- CHD7 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.9); catalogued as rs1393062776, COSV71113021; called by muse, mutect2
- COL4A4 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307670; called by muse, mutect2
- CSMD3 | c.3146T>C p.L1049P (on ENST00000297405 / NM_001363185.1; = p.L945P on NM_052900.3) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV52182779; called by muse, mutect2
- DAB1 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs755758685; called by muse, mutect2, varscan2
- DCDC1 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as COSV60844343; called by muse, mutect2, varscan2
- DIXDC1 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782657124; called by muse, mutect2, varscan2
- ERBB4 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs1229970702, COSV53500900; called by muse, mutect2, varscan2
- FAM135B | c.3346T>G p.L1116V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.918); catalogued as COSV52708161; called by muse, mutect2
- FGG | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.222); catalogued as COSV60195612; called by muse, mutect2, varscan2
- HERC1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs781379594; called by mutect2, varscan2
- HYDIN | c.2000A>T p.Q667L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV55487759; called by muse, mutect2, varscan2
- JAKMIP1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1313972918, COSV51539800; called by muse, mutect2, varscan2
- LEMD3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765045080; called by muse, mutect2
- LYNX1 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV100235857; called by muse, mutect2, varscan2
- MAML3 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as rs774116209, COSV59070708; called by muse, mutect2, varscan2
- ME3 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs770893447; called by muse, mutect2, varscan2
- MFN1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV99764346; called by muse, mutect2, varscan2
- MIA3 | c.5086C>T p.R1696* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as rs1040322499; called by muse, mutect2
- MROH8 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs370293792; called by muse, mutect2, varscan2
- MSH6 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV99316797; called by muse, mutect2
- MYO1B | c.2473C>T p.R825* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | catalogued as rs777573572, COSV99045149; called by muse, mutect2
- NCOA2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383646490; called by muse, mutect2, varscan2
- NRK | c.1454T>G p.V485G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54592881; called by muse, mutect2, varscan2
- OR10AG1 | c.858A>C p.K286N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56634279; called by muse, mutect2
- OR5M3 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392520, COSV56565606; called by muse, mutect2, varscan2
- PARP3 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs368229941; called by muse, mutect2, varscan2
- POLH | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1369683925; called by muse, mutect2
- RC3H1 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV51198224, COSV51206868; called by muse, mutect2, varscan2
- RELN | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV100633949; called by mutect2, varscan2
- SCAF1 | c.2123G>A p.G708D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.476); catalogued as rs1364438026; called by muse, varscan2
- SLC22A13 | c.1379C>A p.S460* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100314674; called by muse, mutect2, varscan2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- SPACA4 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199748130, COSV99614554; called by mutect2, varscan2
- SPART | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV62088240; called by muse, mutect2, varscan2
- SPATS1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV55822189; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3543G>C p.E1181D | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59134587; called by muse, mutect2, varscan2
- TENM1 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64431059; called by muse, mutect2, varscan2
- TLN1 | c.6589C>T p.R2197C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs761387809; called by muse, mutect2, varscan2
- TMEM132D | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs1025938059; called by muse, mutect2, varscan2
- TMEM91 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.349); catalogued as rs370308690; called by muse, mutect2, varscan2
- ZNF22 | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100026485; called by muse, mutect2, varscan2
- AGAP4 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2
- ANXA2 | c.639G>C p.W213C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- BLK | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.133); called by mutect2, varscan2
- CAPN15 | c.2972A>G p.N991S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCT6B | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- CDC14B | c.1341C>A p.L447= | Splice Region (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- CDH23 | c.9544C>A p.P3182T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPO | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF16 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DGKK | c.3569del p.K1190Sfs*8 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- DGKZ | c.1158C>G p.F386L (on ENST00000454345 / NM_001105540.2; = p.F198L on NM_003646.4) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DOK2 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DPPA3 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC1H1 | c.1718G>C p.G573A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- EDEM1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEF1AKNMT | c.261G>T p.M87I (on ENST00000361735 / NM_015935.5; = p.M1? on NM_014955.3) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- EP300 | c.4231A>G p.T1411A | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPX | c.1711T>C p.Y571H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH3 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FGFR1 | c.355T>G p.S119A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOXN2 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2
- FRMD4A | c.353T>C p.F118S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPC5 | c.1266A>C p.E422D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, varscan2
- GRM2 | c.547del p.R183Afs*44 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- HMCN1 | c.2685C>G p.S895R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HNRNPUL2 | c.786C>A p.D262E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.32); called by mutect2, varscan2
- IGKV2-28 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by mutect2, varscan2
- IGLV5-45 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2
- LRCH4 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MFSD4B | c.95C>G p.S32C (on ENST00000368847; = p.F127L on NM_153369.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- MS4A2 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- NIPAL2 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- OFD1 | c.876T>G p.D292E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- OR10Z1 | c.411T>G p.N137K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ORAI3 | c.482T>A p.L161H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI3 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PCSK5 | c.5209G>C p.A1737P | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- PEG10 | c.666G>C p.E222D (on ENST00000482108 / NM_001040152.2; = p.E256D on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PELP1 | c.392G>C p.W131S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PITPNM2 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLSCR5 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- PPP2R2A | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPT2 | c.233_236del p.E78Afs*71 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- PRKDC | c.11365A>G p.R3789G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2
- PSME2 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SAMSN1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.583); called by muse, mutect2
- SEMA4F | c.889T>A p.C297S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B1 | c.1652T>A p.L551* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- SHARPIN | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SLC5A2 | c.479T>C p.F160S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOCS6 | c.1067G>C p.R356T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SPAG6 | c.1198-1G>C p.X400_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- SPATA9 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by mutect2, varscan2
- SPEF2 | c.4761T>G p.D1587E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- STK32A | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SYNE3 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TANGO6 | c.1270C>A p.L424I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TBX20 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TEX55 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TFPI | c.841A>C p.I281L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TIGIT | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2
- TPH1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSGA10 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TTYH2 | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- UBE4B | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UTRN | c.2383C>G p.Q795E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- WDR17 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- XIRP2 | c.6842A>C p.K2281T (on ENST00000628543; = p.K2456T on NM_152381.6) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB49 | c.482C>G p.S161* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- ZFP28 | c.2140T>A p.S714T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF117 | c.264A>C p.E88D | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- ZNF277 | c.1349T>A p.L450Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSWIM8 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO3 | c.1491G>C p.L497= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs776129793; called by muse, mutect2, varscan2
- ARMC1 | c.121C>T p.L41= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2
- ASB9 | c.66C>T p.I22= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- DLK1 | c.828G>A p.P276= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs746060848, COSV57990687; called by muse, mutect2, varscan2
- EPHX3 | c.447C>T p.D149= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- FAM209B | c.42C>G p.L14= | Silent (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- GJA8 | c.714G>A p.R238= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1457222860; called by muse, mutect2, varscan2
- GLI1 | c.432G>T p.G144= | Silent (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- GON4L | c.4572A>G p.P1524= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs607834; called by muse, mutect2
- HBG2 | c.210T>G p.T70= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs768094911, COSV57963509, COSV57963783; called by muse, mutect2
- HYAL4 | c.336C>G p.L112= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- KIAA1109 | c.11076A>G p.S3692= | Silent (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- LYNX1 | c.87C>T p.N29= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs372261422; called by muse, mutect2
- NCOA2 | c.3318C>T p.V1106= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- NEMF | c.3213G>C p.L1071= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- NOTCH3 | c.831G>A p.E277= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs145049433; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NRXN3 | c.1662G>C p.V554= (on ENST00000557594 / NM_001272020.2; = p.V978= on NM_004796.6) | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- OR51G1 | c.684C>T p.L228= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1395936505; called by muse, mutect2, varscan2
- OR52E2 | c.108G>A p.V36= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- POLQ | c.3870A>G p.R1290= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- PSD2 | c.519C>T p.C173= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs529058855, COSV51198522; called by muse, mutect2, varscan2
- RALGAPA2 | c.1713C>T p.L571= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- RESF1 | c.2283T>C p.A761= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs1343632493; called by muse, mutect2, varscan2
- RIPK4 | c.84G>C p.V28= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- SKIV2L | c.1746G>A p.Q582= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- SLC25A53 | c.270G>A p.L90= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- SMC5 | c.405A>G p.V135= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, varscan2
- TRIM14 | c.696G>A p.K232= | Silent (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- WDR61 | c.789G>A p.T263= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs144069115; called by muse, mutect2, varscan2
- ZNF708 | c.78G>A p.Q26= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 7/76 reads (9%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- GATAD2A | c.-90-1062del | Intron (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- NRG1 | c.701-4805T>G | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- OR52A4P | n.863C>T | RNA (SNP) | VAF 3/17 reads (18%) | catalogued as rs1451662715; called by muse, mutect2
- SNORA26 | n.114G>A | RNA (SNP) | VAF 14/100 reads (14%) | catalogued as rs1392443565; called by muse, mutect2, varscan2
- UBTFL2 | n.193G>C | RNA (SNP) | VAF 37/348 reads (11%) | called by muse, mutect2, varscan2
